Surgical pathology report (de-identified scan), TCGA case TCGA-WE-A8ZY, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  Norfolk and Norwich Hospital, specimen TCGA-WE-A8ZY-06A (Metastatic).

ADDRESS FOR REPORT: Plastic Surgery
Copy To: Cancer Registry

CYTOPATHOLOGY REPORT

LAB No:

CASE HISTORY:

Previous melanoma on the back.? Recurrence

MACROSCOPIC:

3 air dried slides dated

Error logged: Insufficient identifiers on slide

MICROSCOPY:

Aspirate contains variably cohesive groups of atypical cells, many of them showing high N/C ratio. Pigment content is also noted within many of the cells. The appearances are entirely in keeping with recurrent malignant melanoma.

DIAGNOSIS:

FNA LUMP ON BACK/LEFT FLANK: CONSISTENT WITH RECURRENT MALIGNANT MELANOMA.

REPORTED BY:

, Consultant Histopathologist.

REPORT DATE:

ICD O 3
Melanoma NOS 8720/3
Site: Back C44.5
20/19/14

Source: NCI Genomic Data Commons file 385fc402-2784-45dc-b62b-20d3424fc7f7 (TCGA-WE-A8ZY.F5CF804D-52CC-4E83-9FD5-E6B5DE63CC61.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).